Somatic mutation profile of tumor specimen TCGA-18-4083-01A (aliquot TCGA-18-4083-01A-01D-1352-08) from TCGA case TCGA-18-4083, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.3 years (23,125 days).
Specimen TCGA-18-4083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a5191e-0b13-4874-b07e-274de86b6d1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-4083-11A (Solid Tissue Normal), aliquot TCGA-18-4083-11A-01D-1352-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1557570e-9a1a-411b-8ed7-5dca07f38e74

The open-access MAF lists 402 somatic variants for this specimen: 310 protein-altering or splice-affecting, 80 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 80, Nonsense Mutation 23, Splice Site 9, Intron 5, RNA 4, Frame Shift Del 3, Translation Start Site 1, 3'Flank 1, 5'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 93/283 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.463A>C p.T155P | Missense Mutation (SNP) | VAF 91/131 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV52661985, COSV52698075, COSV52994812, COSV53498723; called by muse, mutect2, varscan2
- ABCA10 | c.1295G>C p.G432A | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52222236; called by muse, mutect2, varscan2
- ABCB1 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 157/221 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55951681; called by muse, mutect2, varscan2
- ABCD2 | c.1888G>T p.A630S | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV58051908; called by muse, mutect2, varscan2
- ACAN | c.2467C>A p.P823T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as COSV61360582; called by muse, mutect2, varscan2
- ACSM6 | c.578A>T p.Y193F | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV58978512; called by muse, mutect2, varscan2
- ACSS3 | c.1991A>T p.Y664F | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV54091353; called by muse, mutect2, varscan2
- ADAM7 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.34); catalogued as COSV51536434; called by muse, mutect2, varscan2
- ADAMTS16 | c.670A>T p.R224W | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV56989893; called by muse, mutect2, varscan2
- ADAMTS19 | c.1265T>A p.L422* | Nonsense Mutation (SNP) | VAF 75/200 reads (38%) | catalogued as COSV50748578, COSV99176656; called by muse, mutect2, varscan2
- ADAMTS20 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67125622, COSV67131641; called by muse, mutect2, varscan2
- ADAMTS3 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54391686; called by muse, mutect2, varscan2
- ADAMTS5 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV53179217, COSV53180757; called by muse, mutect2, varscan2
- ADGRF5 | c.1910C>G p.T637S | Missense Mutation (SNP) | VAF 143/205 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV51933984; called by muse, mutect2, varscan2
- ADGRV1 | c.5917G>T p.D1973Y | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985325; called by muse, mutect2, varscan2
- ADHFE1 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV52555393; called by muse, mutect2, varscan2
- ADTRP | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV57643108; called by muse, mutect2, varscan2
- AFP | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56925241; called by muse, mutect2, varscan2
- AGA | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140337260; called by muse, mutect2, varscan2
- AHNAK2 | c.12076G>T p.E4026* | Nonsense Mutation (SNP) | VAF 84/495 reads (17%) | catalogued as COSV60915566; called by muse, mutect2, varscan2
- AKR1B10 | c.764A>C p.Q255P | Missense Mutation (SNP) | VAF 379/513 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62055491; called by muse, mutect2, varscan2
- ALKBH3 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100236609, COSV57024112; called by muse, mutect2, varscan2
- ANPEP | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as rs1051223150, COSV55591562; called by muse, mutect2, varscan2
- ARAP3 | c.4336G>T p.D1446Y | Missense Mutation (SNP) | VAF 131/203 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV53350740; called by muse, mutect2, varscan2
- ARHGAP32 | c.4548G>T p.Q1516H (on ENST00000310343 / NM_001378025.1; = p.Q1167H on NM_014715.4) | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV59847961; called by muse, mutect2, varscan2
- ATP10B | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58778834; called by muse, mutect2, varscan2
- ATPAF1 | c.620A>T p.Y207F (on ENST00000574428; = p.Y230F on NM_022745.4) | Missense Mutation (SNP) | VAF 97/417 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV61304981; called by muse, mutect2, varscan2
- AVPR1A | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54546648; called by muse, mutect2, varscan2
- BARHL2 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64981269; called by muse, mutect2, varscan2
- BBS2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 92/420 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs766873519, CM122043, COSV55325736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV64748269; called by muse, mutect2, varscan2
- CAMTA1 | c.1409T>A p.L470H | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57901375; called by muse, mutect2, varscan2
- CARHSP1 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as COSV60683909; called by muse, mutect2, varscan2
- CASK | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 58/154 reads (38%) | catalogued as COSV59366815; called by muse, mutect2, varscan2
- CCDC151 | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62697954; called by muse, mutect2, varscan2
- CCDC68 | c.962C>A p.T321N | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.277); catalogued as COSV61603670; called by muse, mutect2, varscan2
- CCT8L2 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1355278669, COSV63462427; called by muse, mutect2, varscan2
- CD226 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV54612294; called by muse, mutect2, varscan2
- CDH20 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 267/459 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV53009974; called by muse, mutect2, varscan2
- CDH8 | c.2227T>C p.S743P | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54867828; called by muse, mutect2, varscan2
- CDH9 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 188/791 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50288122; called by muse, mutect2, varscan2
- CDK5RAP1 | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 139/254 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as COSV59426909; called by muse, mutect2, varscan2
- CDKN1A | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV55188969; called by muse, mutect2, varscan2
- CEP112 | c.633G>C p.W211C | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101210830; called by muse, mutect2
- CEP63 | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV59676381; called by muse, mutect2, varscan2
- CFAP47 | c.1634A>T p.K545M | Missense Mutation (SNP) | VAF 86/109 reads (79%) | SIFT tolerated (0.31); PolyPhen benign (0.21); catalogued as COSV52884712; called by muse, mutect2, varscan2
- CFHR3 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.208); catalogued as COSV66402213; called by muse, mutect2, varscan2
- CHGB | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV66760520; called by muse, mutect2, varscan2
- CHML | c.470A>C p.H157P | Missense Mutation (SNP) | VAF 107/645 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59364303; called by muse, mutect2, varscan2
- CILP | c.353G>T p.W118L | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56024358; called by muse, varscan2
- CLCN2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 151/684 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55601191; called by muse, mutect2, varscan2
- CLEC9A | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63350339; called by muse, mutect2, varscan2
- CNGB3 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV60689963; called by muse, mutect2, varscan2
- COL16A1 | c.1460A>T p.K487M | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV99594794; called by muse, mutect2
- COL2A1 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 75/309 reads (24%) | catalogued as COSV61530712; called by muse, mutect2, varscan2
- COL3A1 | c.3638C>G p.A1213G | Missense Mutation (SNP) | VAF 264/340 reads (78%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100483239; called by muse, mutect2, varscan2
- COLEC12 | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs531789462, COSV68370658; called by muse, mutect2, varscan2
- CSMD1 | c.6932G>A p.G2311D (on ENST00000520002; = p.G2310D on NM_033225.6) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780060162, COSV59325600; called by muse, mutect2, varscan2
- CSMD2 | c.6199C>A p.P2067T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV53912966; called by muse, mutect2, varscan2
- CSMD3 | c.10172G>T p.R3391L (on ENST00000297405 / NM_001363185.1; = p.R3222L on NM_052900.3) | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs750171856, COSV52100044, COSV52183749; called by muse, mutect2, varscan2
- CTNND2 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 296/536 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58888242, COSV58889653; called by muse, mutect2, varscan2
- DBF4 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 122/151 reads (81%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV55996873; called by muse, mutect2, varscan2
- DEPDC7 | c.505G>C p.A169P (on ENST00000241051 / NM_001077242.2; = p.A160P on NM_139160.2) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53807238; called by muse, mutect2, varscan2
- DEUP1 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs755668855, COSV53212331; called by muse, mutect2, varscan2
- DEUP1 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV53212342; called by muse, mutect2, varscan2
- DGKB | c.1505G>T p.W502L | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51783243; called by muse, mutect2, varscan2
- DISP1 | c.2589G>T p.Q863H | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV52659040; called by muse, mutect2, varscan2
- DMD | c.1982G>C p.S661T | Missense Mutation (SNP) | VAF 115/155 reads (74%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV55871915; called by muse, mutect2, varscan2
- DNAAF1 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV57577311; called by muse, mutect2, varscan2
- DNAH10 | c.6892G>T p.A2298S (on ENST00000409039; = p.A2237S on NM_207437.3) | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68993194, COSV68993911; called by muse, mutect2, varscan2
- DNAH10 | c.7367A>T p.Y2456F (on ENST00000409039; = p.Y2395F on NM_207437.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV68993916; called by muse, mutect2, varscan2
- DNAH3 | c.8012A>T p.E2671V | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54521989; called by muse, mutect2, varscan2
- DNAJB9 | c.598A>G p.S200G | Missense Mutation (SNP) | VAF 285/365 reads (78%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs199929387, COSV50812122; called by muse, mutect2, varscan2
- DPP10 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV59682596, COSV59686954; called by muse, mutect2, varscan2
- DRAM1 | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV51597889; called by muse, mutect2, varscan2
- DSCAM | c.3619G>T p.V1207L | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV68028449; called by muse, mutect2, varscan2
- E2F5 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56274849; called by muse, mutect2, varscan2
- EBF3 | c.841G>A p.V281I (on ENST00000355311 / NM_001375392.1; = p.V272I on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs1336143311, COSV62475190; called by muse, mutect2, varscan2
- EDRF1 | c.3363C>G p.I1121M (on ENST00000356792 / NM_001202438.2; = p.I1087M on NM_015608.2) | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV61763973; called by muse, mutect2, varscan2
- EIF4G1 | c.860G>A p.G287E (on ENST00000346169 / NM_198241.3; = p.G91E on NM_004953.5) | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.996); catalogued as COSV59991037; called by muse, mutect2, varscan2
- ESF1 | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52521009; called by muse, mutect2, varscan2
- FAM124B | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66272095; called by muse, mutect2, varscan2
- FAM155A | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.127); catalogued as COSV101028820; called by muse, mutect2, varscan2
- FANK1 | c.338A>C p.H113P | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV64156492; called by muse, mutect2, varscan2
- FAT1 | c.8134G>C p.V2712L | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV71673959; called by muse, varscan2
- FAT1 | c.8089G>T p.E2697* | Nonsense Mutation (SNP) | VAF 64/234 reads (27%) | catalogued as COSV71672322; called by muse, varscan2
- FBN2 | c.3199G>C p.G1067R | Missense Mutation (SNP) | VAF 97/170 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52513690, COSV52536126; called by muse, mutect2, varscan2
- FBXO21 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 60/620 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV100401781; called by muse, mutect2, varscan2
- FBXO22 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 76/430 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380594; called by muse, mutect2, varscan2
- FEZF1 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 87/119 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV58658778; called by muse, mutect2, varscan2
- FH | c.1246G>C p.V416L | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.174); catalogued as COSV63817502, COSV63818190; called by muse, mutect2, varscan2
- FMN2 | c.2789G>T p.G930V | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.463); catalogued as rs1206150827, COSV60430684; called by muse, varscan2
- FOLH1 | c.1533G>T p.R511S | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1370830109, COSV57049280, COSV99923931; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1925G>T p.C642F | Missense Mutation (SNP) | VAF 192/416 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58554405; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2079C>G p.N693K | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV58548122, COSV58554416; called by muse, mutect2, varscan2
- FRYL | c.2938C>T p.R980* | Nonsense Mutation (SNP) | VAF 42/182 reads (23%) | catalogued as COSV51947284; called by muse, mutect2, varscan2
- FTHL17 | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 117/148 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV63266962; called by muse, mutect2, varscan2
- GABRA1 | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 148/238 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV50104502; called by muse, mutect2, varscan2
- GABRG1 | c.1271C>A p.T424K | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV54954254; called by muse, mutect2, varscan2
- GANC | c.1840G>T p.G614* | Nonsense Mutation (SNP) | VAF 33/168 reads (20%) | catalogued as COSV100531003, COSV58811917; called by muse, mutect2, varscan2
- GLIPR1L1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56881827; called by muse, mutect2
- GPATCH2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 145/387 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777784110, COSV65127728; called by muse, mutect2, varscan2
- GPR142 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 122/163 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.223); catalogued as COSV59519371, COSV59519570; called by muse, mutect2, varscan2
- GRID2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56207021; called by muse, mutect2, varscan2
- GRID2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.017); catalogued as COSV56207032; called by muse, mutect2, varscan2
- GUCY1A2 | c.1489A>T p.I497F | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV56486851; called by muse, mutect2, varscan2
- HACD1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV63516428; called by muse, mutect2, varscan2
- HCN1 | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.165); catalogued as COSV100300988, COSV99079148; called by muse, mutect2, varscan2
- HDX | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 246/297 reads (83%) | SIFT tolerated (0.26); PolyPhen benign (0.265); catalogued as COSV52973294; called by muse, mutect2, varscan2
- HECTD1 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV67946347; called by muse, mutect2, varscan2
- HEPHL1 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV59892072; called by muse, mutect2, varscan2
- HERPUD1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 182/628 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.212); catalogued as COSV55862196; called by muse, mutect2, varscan2
- HLTF | c.2873C>T p.T958I | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV59500771; called by muse, varscan2
- HNRNPM | c.631C>T p.L211= | Splice Region (SNP) | VAF 97/486 reads (20%) | catalogued as COSV57692689; called by muse, mutect2, varscan2
- HRH2 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51573522; called by muse, mutect2, varscan2
- ICE1 | c.3059G>A p.S1020N | Missense Mutation (SNP) | VAF 56/405 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56825201; called by muse, mutect2, varscan2
- ICE2 | c.1090A>G p.M364V | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs905553050, COSV55031469; called by muse, mutect2, varscan2
- IFT172 | c.396A>T p.E132D | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53133779; called by muse, mutect2, varscan2
- IGKV1D-13 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 69/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1481503644; called by muse, mutect2, varscan2
- IGKV1D-16 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1303917349; called by muse, mutect2, varscan2
- IGKV2-28 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as rs766284150; called by muse, mutect2, varscan2
- IGLV5-45 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 97/522 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs571507588; called by muse, varscan2
- IL17RA | c.376T>A p.C126S | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60053275; called by muse, mutect2, varscan2
- IL27RA | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54600778; called by muse, mutect2, varscan2
- INSYN2A | c.1422G>A p.W474* | Nonsense Mutation (SNP) | VAF 291/513 reads (57%) | catalogued as COSV54740237; called by muse, mutect2, varscan2
- INTS5 | c.1734G>T p.L578F | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57951556; called by muse, mutect2, varscan2
- IQCE | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 116/183 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs917185268, COSV58078427; called by muse, mutect2, varscan2
- IRAK3 | c.1777T>C p.Y593H | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV54161868; called by muse, mutect2, varscan2
- ISM1 | c.1372T>C p.F458L | Missense Mutation (SNP) | VAF 93/186 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52604866; called by muse, mutect2, varscan2
- KATNIP | c.1930C>T p.H644Y | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV55180692; called by muse, mutect2, varscan2
- KCNK9 | c.500G>C p.C167S | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.981); catalogued as COSV57281814; called by muse, mutect2, varscan2
- KIF20A | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV67509826; called by muse, mutect2, varscan2
- KLHL6 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 63/691 reads (9%) | catalogued as rs773968370, COSV100384792; called by muse, mutect2
- KLRG2 | c.356G>T p.W119L | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV61800831; called by muse, mutect2, varscan2
- KMT2D | c.16521G>C p.E5507D | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56440273; called by muse, mutect2, varscan2
- KRT3 | c.570G>C p.Q190H | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs767671394, COSV58815636; called by muse, mutect2, varscan2
- KRTAP10-7 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 191/276 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59110384; called by muse, mutect2, varscan2
- LAIR2 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 62/272 reads (23%) | catalogued as COSV56621529; called by muse, mutect2, varscan2
- LDB2 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV58762745, COSV58769584; called by muse, mutect2, varscan2
- LEPR | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV60755192; called by muse, mutect2, varscan2
- LILRA1 | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 168/355 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.51); catalogued as COSV52180834, COSV52183788; called by muse, mutect2
- LILRB2 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 205/468 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV58745289; called by muse, mutect2, varscan2
- LMBRD1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV65297283, COSV65298460; called by muse, mutect2, varscan2
- LMLN | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 48/584 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.112); catalogued as COSV54563511, COSV99502448; called by muse, mutect2
- LRFN5 | c.2007C>A p.N669K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as COSV53256630, COSV53278716; called by muse, mutect2, varscan2
- LRP1B | c.13663A>G p.T4555A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67221194, COSV67258307; called by muse, mutect2, varscan2
- LRP5 | c.4112-1G>C p.X1371_splice | Splice Site (SNP) | VAF 39/232 reads (17%) | catalogued as COSV53715900; called by muse, mutect2, varscan2
- MADD | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1195327978, COSV100211611; called by muse, mutect2, varscan2
- MATK | c.431T>C p.F144S (on ENST00000310132 / NM_139355.3; = p.F145S on NM_002378.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59554567; called by muse, mutect2, varscan2
- MDGA2 | c.1429A>G p.K477E (on ENST00000399232 / NM_001113498.2; = p.K179E on NM_182830.4) | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV62093263; called by muse, mutect2, varscan2
- METTL17 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 35/170 reads (21%) | catalogued as COSV59555995; called by muse, mutect2, varscan2
- MFSD14B | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 172/231 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as rs757093123, COSV64700883; called by muse, mutect2, varscan2
- MKX | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as rs1401981489, COSV101008892, COSV65392201; called by muse, mutect2, varscan2
- MMP8 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52632629; called by muse, mutect2, varscan2
- MRPL17 | c.244-2A>T p.X82_splice | Splice Site (SNP) | VAF 57/235 reads (24%) | catalogued as COSV56618952, COSV99996887; called by muse, mutect2, varscan2
- MS4A14 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV55734976; called by muse, mutect2, varscan2
- MSH3 | c.3197G>A p.R1066K | Missense Mutation (SNP) | VAF 165/244 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV54152064; called by muse, mutect2, varscan2
- MUC16 | c.21481G>A p.E7161K | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as COSV67466524; called by muse, mutect2, varscan2
- MUC16 | c.2675C>G p.S892C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs1243055171, COSV101201778, COSV67466526; called by muse, mutect2, varscan2
- MUC21 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 124/440 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs1333329465, COSV66220857; called by muse, varscan2
- MUC6 | c.3767C>A p.P1256Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV70141734; called by muse, mutect2, varscan2
- MYCBP2 | c.5450G>C p.G1817A (on ENST00000357337; = p.G1855A on NM_015057.5) | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV62019595; called by muse, mutect2, varscan2
- MYH14 | c.3130A>G p.K1044E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV51818043; called by muse, mutect2, varscan2
- MYLK2 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV65659074; called by muse, mutect2, varscan2
- MYLK2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769968444, COSV65659078; called by muse, mutect2, varscan2
- MYSM1 | c.1775A>T p.H592L | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68977497; called by muse, mutect2, varscan2
- NAALADL1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 99/344 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV60523707; called by muse, mutect2, varscan2
- NDST4 | c.1161C>A p.H387Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52120123; called by muse, mutect2, varscan2
- NEO1 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.254); catalogued as COSV56071289; called by muse, mutect2, varscan2
- NID1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 119/310 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs568556688, COSV51620446; called by muse, mutect2, varscan2
- NINL | c.3755G>A p.R1252Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs747375078, COSV54002701; called by muse, mutect2, varscan2
- NLGN1 | c.2284T>A p.Y762N | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64324814; called by muse, mutect2
- NLGN4X | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 156/199 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV52018138, COSV99320844; called by muse, mutect2, varscan2
- NLRP3 | c.2643G>C p.Q881H | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60224443; called by muse, mutect2, varscan2
- NPAT | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV53718093; called by muse, mutect2, varscan2
- NSD1 | c.5896G>T p.E1966* | Nonsense Mutation (SNP) | VAF 20/328 reads (6%) | catalogued as COSV100729467; called by muse, mutect2
- OPRL1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 116/197 reads (59%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV61091733; called by muse, mutect2, varscan2
- OR11H6 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV59644265, COSV59645491; called by muse, mutect2, varscan2
- OR2M3 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 563/1300 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV71759050; called by muse, mutect2, varscan2
- OR2T1 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 233/649 reads (36%) | catalogued as rs1296415026, COSV63541934; called by muse, mutect2, varscan2
- OR2T2 | c.105C>G p.I35M | Missense Mutation (SNP) | VAF 131/692 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as rs528774471, COSV61618126, COSV61618913; called by muse, mutect2, varscan2
- OR2T4 | c.213G>T p.L71F | Missense Mutation (SNP) | VAF 302/812 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs372778082, COSV63544045; called by muse, mutect2, varscan2
- OR4K17 | c.42G>T p.L14F | Missense Mutation (SNP) | VAF 118/559 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV59648105; called by muse, mutect2, varscan2
- OR4X1 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60722892; called by muse, mutect2, varscan2
- OR5D14 | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59456347; called by muse, mutect2, varscan2
- OR5D18 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs940409897, COSV61737147; called by muse, mutect2, varscan2
- OR5J2 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs900892601, COSV56621296, COSV56623773; called by muse, mutect2, varscan2
- OR6K3 | c.814C>G p.L272V (on ENST00000368146; = p.L256V on NM_001005327.2) | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.173); catalogued as COSV63745198, COSV63745666; called by muse, mutect2, varscan2
- OR6K6 | c.311C>T p.T104I (on ENST00000368144; = p.T80I on NM_001005184.1) | Missense Mutation (SNP) | VAF 88/457 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV63744179; called by muse, mutect2, varscan2
- OR8B8 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 175/361 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV60144574; called by muse, mutect2, varscan2
- OR8H2 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 219/1012 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57944630; called by muse, mutect2, varscan2
- OSTN | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 72/589 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760770385, COSV59139750; called by muse, mutect2, varscan2
- PANX1 | c.950T>A p.V317D | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV57133829; called by muse, mutect2, varscan2
- PARD3B | c.2137C>T p.L713F | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100594002; called by muse, mutect2
- PCDHB3 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 123/217 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50574236, COSV99166875; called by muse, mutect2, varscan2
- PCDHGA8 | c.2243C>G p.A748G | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV53949385; called by muse, mutect2, varscan2
- PFAS | c.1883A>T p.E628V | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV58980384; called by muse, mutect2, varscan2
- PLEKHA1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64569512; called by muse, mutect2, varscan2
- PLSCR1 | c.867G>C p.M289I | Missense Mutation (SNP) | VAF 145/272 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as COSV61012858; called by muse, mutect2, varscan2
- PNCK | c.462G>T p.M154I (on ENST00000340888 / NM_001366975.1; = p.M237I on NM_001039582.3) | Missense Mutation (SNP) | VAF 135/190 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV61743851; called by muse, mutect2, varscan2
- POLG2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs373387408; called by muse, mutect2, varscan2
- POLK | c.2543C>A p.T848K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV54035277; called by muse, mutect2, varscan2
- POLN | c.2491G>C p.V831L | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV59051288; called by muse, mutect2, varscan2
- PPP3CB | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55019261; called by muse, mutect2, varscan2
- PRAMEF8 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1218205281; called by muse, mutect2, varscan2
- PRDM9 | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 259/566 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57006406; called by muse, varscan2
- PRKAR2B | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 189/239 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104378753, COSV55924915; called by muse, mutect2, varscan2
- PRMT9 | c.2420C>G p.S807C | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56853667; called by muse, mutect2, varscan2
- PSMD13 | c.88A>T p.T30S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV61501037; called by muse, varscan2
- PTGER4 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56720564, COSV56721739; called by muse, mutect2
- PTPN18 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51558954; called by muse, mutect2, varscan2
- PTPRD | c.1175G>T p.R392M | Missense Mutation (SNP) | VAF 88/561 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV100645375; called by muse, mutect2, varscan2
- PTPRT | c.859+1G>T p.X287_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | catalogued as COSV61981730; called by muse, varscan2
- PTPRT | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV61965308, COSV61997986; called by muse, mutect2, varscan2
- PUDP | c.394A>T p.S132C | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs764938270, COSV66904021; called by muse, mutect2, varscan2
- PXMP4 | c.176+1G>T p.X59_splice | Splice Site (SNP) | VAF 93/414 reads (22%) | catalogued as rs1286280072, COSV54133263; called by muse, mutect2, varscan2
- PXMP4 | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV54133278; called by muse, mutect2, varscan2
- RAG1 | c.2917C>A p.R973S | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as CM1313162, COSV55024644, COSV55025338; called by muse, mutect2, varscan2
- RCN1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV50014564; called by muse, mutect2, varscan2
- REG1B | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 75/420 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV59305662; called by muse, varscan2
- REG1B | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59305675, COSV59307540; called by muse, varscan2
- REV3L | c.5323T>C p.S1775P | Missense Mutation (SNP) | VAF 121/347 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV62619037; called by muse, mutect2, varscan2
- REXO1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368328980; called by muse, mutect2, varscan2
- RGS7 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58542110; called by muse, mutect2, varscan2
- RGS7 | c.176-1G>A p.X59_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV58542120; called by muse, mutect2, varscan2
- RHOC | c.217T>G p.S73A | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV53517610; called by muse, mutect2, varscan2
- RNF103 | c.1196C>A p.T399K | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV52894948, COSV52895979; called by muse, mutect2, varscan2
- RP1 | c.6331G>A p.V2111I | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55116921; called by muse, mutect2, varscan2
- RYR2 | c.12173A>T p.Y4058F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as COSV63686081; called by muse, mutect2, varscan2
- RYR2 | c.12826G>T p.V4276L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV63686088; called by muse, mutect2, varscan2
- RYR3 | c.7813A>G p.M2605V (on ENST00000389232; = p.M2606V on NM_001036.6) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV66789702; called by muse, mutect2, varscan2
- SALL1 | c.346C>G p.H116D | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV51757521; called by muse, mutect2, varscan2
- SEL1L | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as rs766722599, COSV60920545; called by muse, mutect2, varscan2
- SEMA3E | c.1806T>A p.C602* | Nonsense Mutation (SNP) | VAF 403/498 reads (81%) | catalogued as COSV57090583; called by muse, mutect2, varscan2
- SF3A2 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV55554705, COSV99677641; called by muse, mutect2, varscan2
- SI | c.4836G>T p.L1612F | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.906); catalogued as rs770794869, COSV52278981; called by muse, mutect2, varscan2
- SIGLEC9 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.085); catalogued as COSV51584466; called by muse, mutect2, varscan2
- SIRT2 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV50875251, COSV99979675; called by muse, mutect2, varscan2
- SLC13A1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 113/148 reads (76%) | SIFT tolerated (0.94); PolyPhen benign (0.065); catalogued as COSV52008167, COSV52011414; called by muse, mutect2, varscan2
- SLC15A4 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1210026352, COSV57161538; called by muse, mutect2, varscan2
- SLC27A4 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55959957, COSV55961578; called by muse, mutect2, varscan2
- SLC38A4 | c.949A>G p.S317G | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56967537; called by muse, mutect2, varscan2
- SLC4A1 | c.2423G>C p.R808P | Missense Mutation (SNP) | VAF 122/177 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM973089, COSV52260138, COSV52262764; called by muse, mutect2, varscan2
- SLC5A11 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 107/487 reads (22%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.674); catalogued as COSV61741672; called by muse, mutect2, varscan2
- SLC6A15 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs767563354, COSV57023897, COSV57025500; called by muse, mutect2, varscan2
- SLCO1A2 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56602195; called by muse, mutect2, varscan2
- SLITRK3 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 160/1228 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.142); catalogued as COSV53848532, COSV53850603; called by muse, mutect2, varscan2
- SPATA6L | c.574A>C p.T192P (on ENST00000461761 / NM_001353484.2; = p.T134P on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV56305208; called by muse, mutect2, varscan2
- SPINK5 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 109/149 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56254029; called by muse, mutect2, varscan2
- SREBF1 | c.2567G>A p.S856N | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55393124; called by muse, mutect2, varscan2
- SSNA1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as COSV100119132, COSV58808941; called by muse, varscan2
- STK36 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 69/102 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs1462556225, COSV55307429; called by muse, mutect2, varscan2
- SUV39H1 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 59/77 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61920789; called by muse, mutect2, varscan2
- SYNDIG1L | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV59047518, COSV59048052; called by muse, mutect2, varscan2
- SYNE1 | c.13021A>T p.T4341S (on ENST00000367255 / NM_182961.4; = p.T4270S on NM_033071.3) | Missense Mutation (SNP) | VAF 167/256 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV54983919; called by muse, mutect2, varscan2
- SYT1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV54048280; called by muse, mutect2, varscan2
- SYT16 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.313); catalogued as rs1333500903, COSV70856621; called by muse, mutect2, varscan2
- TAF1L | c.5245G>T p.E1749* | Nonsense Mutation (SNP) | VAF 23/614 reads (4%) | catalogued as COSV99644906; called by muse, mutect2
- TAF4B | c.2002+1G>C p.X668_splice | Splice Site (SNP) | VAF 74/178 reads (42%) | catalogued as COSV52303900; called by muse, mutect2, varscan2
- TAFA5 | c.291T>A p.C97* (on ENST00000402357 / NM_001082967.3; = p.C90* on NM_015381.7) | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV60979507; called by muse, varscan2
- TBX20 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as COSV68783624; called by muse, mutect2, varscan2
- TDRD5 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 294/645 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1162851507, COSV54242910; called by muse, mutect2, varscan2
- TGFA | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782074408, COSV54913414, COSV54913742; called by muse, mutect2, varscan2
- TIMELESS | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 52/160 reads (33%) | catalogued as rs777449396, COSV57511426, COSV57514001; called by mutect2, varscan2
- TMEM132B | c.1278+1G>C p.X426_splice | Splice Site (SNP) | VAF 63/205 reads (31%) | catalogued as COSV54754040; called by muse, mutect2, varscan2
- TMEM87B | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as rs778315618, COSV51713282; called by muse, mutect2, varscan2
- TMPRSS7 | c.2299G>T p.G767W (on ENST00000452346; = p.G641W on NM_001042575.2) | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69980712; called by muse, mutect2, varscan2
- TNC | c.5074G>T p.G1692* | Nonsense Mutation (SNP) | VAF 155/650 reads (24%) | catalogued as COSV60785058; called by muse, mutect2, varscan2
- TNK2 | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.524); catalogued as COSV100361049, COSV100361454; called by muse, mutect2
- TNNI3K | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 108/369 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as COSV58554424, COSV58563814; called by muse, mutect2, varscan2
- TRAT1 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55468589; called by muse, mutect2, varscan2
- TRIO | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100710228, COSV60083986; called by muse, mutect2, varscan2
- TSHZ1 | c.2632G>T p.E878* (on ENST00000580243 / NM_001308210.2; = p.E833* on NM_005786.6) | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | catalogued as COSV59009457; called by muse, mutect2
- TTC14 | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 48/546 reads (9%) | catalogued as rs1280643968, COSV99932145; called by muse, mutect2
- TTC21B | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54630689, COSV54631675; called by muse, mutect2, varscan2
- TYR | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM128798, HM040129, COSV54475708; called by muse, mutect2, varscan2
- UBE2NL | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs868986572; called by muse, mutect2, varscan2
- UBQLN3 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 139/286 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61164223; called by muse, varscan2
- UNC5D | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs1270541009, COSV54794875; called by muse, mutect2, varscan2
- UNKL | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV57019615; called by muse, mutect2, varscan2
- USH2A | c.3442C>A p.P1148T | Missense Mutation (SNP) | VAF 147/389 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56351696, COSV56370553; called by muse, mutect2, varscan2
- USP33 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs946502612, COSV62469493; called by muse, mutect2, varscan2
- USP40 | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52481012, COSV99295602; called by muse, mutect2, varscan2
- USP7 | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100784466, COSV61214704; called by muse, mutect2, varscan2
- WDR36 | c.965A>G p.K322R | Missense Mutation (SNP) | VAF 108/166 reads (65%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV72411170; called by muse, mutect2, varscan2
- WDR49 | c.1268C>G p.S423W (on ENST00000308378 / NM_001366158.1; = p.S764W on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV57705394, COSV57708425; called by muse, mutect2, varscan2
- WDR75 | c.2377C>G p.Q793E | Missense Mutation (SNP) | VAF 91/110 reads (83%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV59105572; called by muse, mutect2, varscan2
- ZFC3H1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 198/482 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.085); catalogued as COSV57348632; called by muse, mutect2, varscan2
- ZFYVE9 | c.2240C>G p.A747G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as COSV55093978; called by muse, mutect2, varscan2
- ZNF229 | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV52161954; called by muse, mutect2, varscan2
- ZNF296 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54319659; called by muse, mutect2, varscan2
- ZNF320 | c.1421G>T p.C474F | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV67088134; called by muse, mutect2, varscan2
- ZNF461 | c.1448A>T p.H483L | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64453698; called by muse, mutect2, varscan2
- ZNF462 | c.3511del p.A1171Pfs*6 | Frame Shift Del (DEL) | VAF 64/301 reads (21%) | catalogued as COSV52948224; called by pindel, varscan2
- ZNF516 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1402760175, COSV71587027; called by muse, mutect2, varscan2
- ZNF527 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs759632113, COSV62230584; called by muse, mutect2, varscan2
- ZNF600 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 128/606 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57742691; called by muse, mutect2, varscan2
- ZNF700 | c.1391A>T p.H464L | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54312458; called by muse, mutect2, varscan2
- ZNF775 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as rs756185273, COSV61613630, COSV61614225; called by muse, mutect2, varscan2
- ZWINT | c.423+1G>T p.X141_splice | Splice Site (SNP) | VAF 140/483 reads (29%) | catalogued as rs1416460568, COSV59185429; called by muse, mutect2, varscan2
- ZYG11B | c.1975G>T p.G659C | Missense Mutation (SNP) | VAF 151/313 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV53753101, COSV53755366; called by muse, mutect2, varscan2
- ANAPC13 | c.207del p.I72Lfs*48 | Frame Shift Del (DEL) | VAF 57/308 reads (19%) | called by mutect2, pindel, varscan2
- FRG2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGLV5-37 | c.253A>C p.S85R | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- LILRA1 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LILRB3 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- PCDH7 | c.2660T>A p.L887Q | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFRSF18 | c.522del p.A175Pfs*6 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- VCX3A | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 74/603 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.188); called by muse, varscan2
- ABCC1 | c.453C>T p.A151= | Silent (SNP) | VAF 68/274 reads (25%) | catalogued as rs1198778723, COSV60686095; called by muse, mutect2, varscan2
- ACTRT2 | c.306C>A p.P102= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV101007622; called by muse, mutect2, varscan2
- ADAM9 | c.1905A>T p.V635= | Silent (SNP) | VAF 42/307 reads (14%) | catalogued as COSV65960126; called by muse, mutect2, varscan2
- ADAMTS20 | c.5637A>G p.R1879= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV67131633; called by muse, mutect2, varscan2
- AFAP1L1 | c.1860G>C p.R620= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV57045295, COSV57046381; called by muse, mutect2
- AHNAK2 | c.7323C>T p.D2441= | Silent (SNP) | VAF 28/514 reads (5%) | catalogued as rs747170564, COSV60929534; called by muse, mutect2
- AL592490.1 | c.780G>A p.V260= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as COSV69426289; called by muse, mutect2, varscan2
- ALMS1 | c.3798A>T p.S1266= | Silent (SNP) | VAF 75/253 reads (30%) | catalogued as COSV52510052; called by muse, mutect2, varscan2
- BCAS1 | c.564C>T p.P188= | Silent (SNP) | VAF 210/523 reads (40%) | catalogued as rs1186299013, COSV65086026; called by muse, mutect2, varscan2
- CASK | c.912A>C p.L304= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV59366824; called by muse, mutect2, varscan2
- CCDC9B | c.84C>T p.L28= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV66875456; called by muse, mutect2, varscan2
- CLECL1 | c.207G>A p.V69= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV59931383; called by muse, mutect2, varscan2
- CLUAP1 | c.994C>A p.R332= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100489706; called by muse, mutect2
- CR2 | c.1596T>A p.V532= | Silent (SNP) | VAF 72/163 reads (44%) | catalogued as COSV65507640; called by muse, mutect2, varscan2
- CSMD3 | c.5322A>C p.L1774= (on ENST00000297405 / NM_001363185.1; = p.L1670= on NM_052900.3) | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV52183766; called by muse, mutect2, varscan2
- CUL9 | c.6732G>A p.E2244= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs774463845, COSV52728647; called by muse, mutect2, varscan2
- CXCL2 | c.255T>C p.C85= | Silent (SNP) | VAF 84/253 reads (33%) | catalogued as rs758110362, COSV56021716; called by muse, mutect2, varscan2
- DCAF4L2 | c.429G>T p.L143= | Silent (SNP) | VAF 51/209 reads (24%) | catalogued as COSV60478747; called by muse, mutect2, varscan2
- DIP2A | c.2874G>T p.L958= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV59477609; called by muse, mutect2, varscan2
- DNAH11 | c.6924G>T p.P2308= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as COSV100179620; called by muse, mutect2, varscan2
- DOCK2 | c.3015C>T p.N1005= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV56959109; called by muse, mutect2, varscan2
- DOLK | c.1326C>T p.A442= | Silent (SNP) | VAF 93/244 reads (38%) | catalogued as rs762899278, COSV58280833; called by muse, mutect2, varscan2
- DSP | c.2079A>T p.L693= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV65792810; called by muse, mutect2, varscan2
- DVL3 | c.444G>T p.R148= | Silent (SNP) | VAF 24/322 reads (7%) | catalogued as COSV100493706; called by muse, mutect2
- E2F8 | c.2478C>T p.T826= | Silent (SNP) | VAF 50/193 reads (26%) | catalogued as rs758439260, COSV51463509; called by muse, mutect2, varscan2
- FBN1 | c.2022G>A p.L674= | Silent (SNP) | VAF 40/276 reads (14%) | catalogued as rs794728182, COSV57316835; called by muse, mutect2, varscan2
- FBXO2 | c.864C>T p.T288= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV62813605; called by muse, mutect2, varscan2
- FERD3L | c.276C>A p.P92= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs200056012, COSV99284998; called by muse, mutect2, varscan2
- FRA10AC1 | c.750A>G p.L250= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV63272088; called by muse, mutect2, varscan2
- GGT5 | c.714G>C p.G238= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- GLIS3 | c.1020C>T p.G340= | Silent (SNP) | VAF 37/198 reads (19%) | catalogued as rs774796300, COSV60929067; called by muse, mutect2, varscan2
- GRIK2 | c.513C>A p.T171= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV100022297, COSV59737249; called by muse, mutect2, varscan2
- GRK7 | c.97C>A p.R33= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV53822979, COSV53825673; called by muse, mutect2, varscan2
- GSTM5 | c.622T>C p.L208= | Silent (SNP) | VAF 142/265 reads (54%) | catalogued as COSV56658122; called by muse, mutect2, varscan2
- HCN1 | c.930C>T p.H310= | Silent (SNP) | VAF 97/184 reads (53%) | catalogued as rs1367657574, COSV57511200; called by muse, mutect2, varscan2
- HOXA11 | c.333G>A p.S111= | Silent (SNP) | VAF 145/232 reads (63%) | catalogued as COSV50053119; called by muse, mutect2, varscan2
- IGHE | c.642G>C p.P214= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as rs781897805; called by muse, mutect2, varscan2
- IQCN | c.2968C>A p.R990= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as COSV62747632; called by muse, mutect2, varscan2
- ITGA7 | c.3465C>T p.G1155= (on ENST00000555728; = p.G1111= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs747512414, COSV57695318; called by muse, mutect2, varscan2
- KCNH5 | c.889C>T p.L297= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV59760596; called by muse, mutect2, varscan2
- KYAT3 | c.870C>G p.G290= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as COSV53101330; called by muse, mutect2, varscan2
- MED12L | c.5514A>G p.R1838= | Silent (SNP) | VAF 179/371 reads (48%) | catalogued as COSV56379214; called by muse, mutect2, varscan2
- MPEG1 | c.1443C>T p.G481= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs1451324388, COSV57090858; called by muse, mutect2, varscan2
- MSLNL | c.63C>G p.T21= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV50100633; called by muse, mutect2, varscan2
- MUC20 | c.318C>T p.I106= | Silent (SNP) | VAF 28/265 reads (11%) | catalogued as rs750225014, COSV57852080; called by mutect2, varscan2
- NCF2 | c.1578C>G p.V526= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as COSV61631458; called by muse, mutect2, varscan2
- NDNF | c.45C>T p.L15= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV65633481; called by muse, mutect2, varscan2
- NOD1 | c.642G>A p.R214= | Silent (SNP) | VAF 59/334 reads (18%) | catalogued as rs754944680, COSV56112576; called by muse, mutect2, varscan2
- OPN1SW | c.1041C>G p.P347= | Silent (SNP) | VAF 144/186 reads (77%) | catalogued as COSV50821756; called by muse, mutect2, varscan2
- OR2B3 | c.912G>T p.L304= | Silent (SNP) | VAF 54/109 reads (50%) | catalogued as COSV65850944; called by muse, mutect2, varscan2
- OR4K5 | c.237T>A p.P79= | Silent (SNP) | VAF 188/1797 reads (10%) | catalogued as COSV100262432; called by muse, mutect2, varscan2
- OR56B4 | c.300C>A p.L100= | Silent (SNP) | VAF 63/244 reads (26%) | catalogued as COSV57204555; called by muse, mutect2, varscan2
- PAPOLA | c.550C>T p.L184= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99354359; called by muse, mutect2
- PLA1A | c.1338T>A p.T446= | Silent (SNP) | VAF 183/323 reads (57%) | catalogued as COSV56331817; called by muse, mutect2, varscan2
- PLXND1 | c.3333C>T p.P1111= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV60713450; called by muse, mutect2, varscan2
- POM121L12 | c.477C>T p.R159= | Silent (SNP) | VAF 58/93 reads (62%) | catalogued as COSV68692973; called by muse, mutect2, varscan2
- PRDM9 | c.2241C>A p.P747= | Silent (SNP) | VAF 258/564 reads (46%) | catalogued as COSV57006417; called by muse, varscan2
- PSD4 | c.1434C>A p.G478= | Silent (SNP) | VAF 76/167 reads (46%) | catalogued as COSV55526790; called by muse, mutect2, varscan2
- REG1B | c.90T>A p.P30= | Silent (SNP) | VAF 76/422 reads (18%) | catalogued as COSV59305652; called by muse, varscan2
- SAGE1 | c.1386C>A p.S462= | Silent (SNP) | VAF 172/228 reads (75%) | catalogued as COSV61013484, COSV61016956; called by muse, varscan2
- SAP30 | c.208C>A p.R70= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV56634824; called by muse, mutect2
- SLC52A3 | c.306C>T p.G102= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1050160028, COSV54077466; called by muse, mutect2
- SLC9C1 | c.1854C>T p.Y618= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as rs1484372413, COSV59887455, COSV59888251; called by muse, mutect2, varscan2
- SON | c.6387G>A p.S2129= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as rs552052844, COSV51657045, COSV51657984; called by muse, mutect2, varscan2
- SOX17 | c.421C>A p.R141= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52025727; called by muse, mutect2, varscan2
- SPATA31D1 | c.2016C>T p.I672= | Silent (SNP) | VAF 60/219 reads (27%) | catalogued as COSV61195914; called by muse, mutect2, varscan2
- SPTA1 | c.3825G>A p.Q1275= | Silent (SNP) | VAF 79/287 reads (28%) | catalogued as COSV63753233; called by muse, mutect2, varscan2
- STRN4 | c.1158C>G p.V386= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV54418494; called by muse, mutect2, varscan2
- SYNE1 | c.6303C>T p.V2101= (on ENST00000367255 / NM_182961.4; = p.V2108= on NM_033071.3) | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV104375155, COSV54983965; called by muse, mutect2, varscan2
- TBC1D1 | c.984C>T p.H328= | Silent (SNP) | VAF 182/580 reads (31%) | catalogued as rs761845611, COSV54719136; called by muse, mutect2, varscan2
- TGM5 | c.927T>C p.D309= (on ENST00000220420 / NM_201631.4; = p.D227= on NM_004245.4) | Silent (SNP) | VAF 69/335 reads (21%) | catalogued as COSV55010071; called by muse, mutect2, varscan2
- TMF1 | c.36C>T p.F12= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV62739493; called by muse, varscan2
- TNKS1BP1 | c.2067G>T p.L689= | Silent (SNP) | VAF 75/145 reads (52%) | catalogued as COSV64101089; called by muse, mutect2, varscan2
- TRPM3 | c.2874C>G p.V958= (on ENST00000357533 / NM_001366142.2; = p.V801= on NM_020952.6) | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as COSV62585998; called by muse, mutect2, varscan2
- UBE2NL | c.36C>A p.T12= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- UGT2A3 | c.1497G>C p.V499= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV52359998; called by muse, mutect2, varscan2
- USP34 | c.6834A>G p.T2278= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs753531958, COSV68401415; called by muse, mutect2, varscan2
- VRTN | c.1164G>A p.E388= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV56441090; called by muse, mutect2, varscan2
- ZNF208 | c.1230A>C p.S410= | Silent (SNP) | VAF 50/224 reads (22%) | catalogued as rs547126951, COSV68101916; called by muse, mutect2, varscan2
- ZNF883 | c.156G>A p.R52= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV101432637, COSV71309079; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845541 G>T | 5'Flank (SNP) | VAF 134/158 reads (85%) | called by muse, varscan2
- ARMC4 | c.-1C>T | 5'UTR (SNP) | VAF 22/77 reads (29%) | catalogued as rs1033978390, COSV100537019; called by muse, mutect2, varscan2
- ASIC2 | c.556-179842G>A | Intron (SNP) | VAF 22/38 reads (58%) | catalogued as rs750939331, COSV99860430; called by muse, mutect2, varscan2
- CAMK2D | c.985-2440_985-2421del | Intron (DEL) | VAF 9/89 reads (10%) | called by mutect2, pindel
- CSMD3 | c.178+59880G>T | Intron (SNP) | VAF 64/164 reads (39%) | catalogued as COSV99838088; called by muse, varscan2
- DCHS2 | n.4314G>T | RNA (SNP) | VAF 59/172 reads (34%) | catalogued as rs1415166495, COSV61772191; called by muse, mutect2, varscan2
- DCHS2 | n.79A>G | RNA (SNP) | VAF 20/85 reads (24%) | catalogued as COSV59726659; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055898 A>G | 3'Flank (SNP) | VAF 44/85 reads (52%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.198C>A | RNA (SNP) | VAF 16/331 reads (5%) | called by muse, mutect2
- MASP1 | c.1303+4968del | Intron (DEL) | VAF 96/921 reads (10%) | catalogued as COSV56222508; called by mutect2, pindel, varscan2
- PLEC | c.523+4928G>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as COSV59637289; called by muse, varscan2
- SNORD116-21 | n.78G>T | RNA (SNP) | VAF 98/468 reads (21%) | catalogued as rs745461800; called by muse, mutect2, varscan2
